Surgical pathology report (de-identified scan), TCGA case TCGA-D1-A0ZS, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Mayo Clinic, specimen TCGA-D1-A0ZS-01A (Primary Tumor).

[page 1 of 4]
1/17/11 *lu***DIAGNOSIS:**

A. Lymph nodes, para-aortic above the inferior mesenteric artery,

lymphadenectomy: Multiple (9) para-aortic lymph nodes above the inferior mesenteric artery are negative for metastatic adenocarcinoma.

B. Lymph nodes, para-aortic below the inferior mesenteric artery,

lymphadenectomy: Multiple (10) para-aortic lymph nodes below the inferior mesenteric artery are negative for metastatic adenocarcinoma.

C. Lymph nodes, right pelvic, lymphadenectomy: Multiple (14) right

pelvic lymph nodes are negative for metastatic adenocarcinoma.

D. Lymph nodes, left pelvic, lymphadenectomy: Multiple (13) left

pelvic lymph nodes are negative for metastatic adenocarcinoma.

E. Uterus, bilateral ovaries and fallopian tubes; hysterectomy and

bilateral salpingo-oophorectomy: FIGO grade 3 (of 3) endometrial

X adenocarcinoma, endometrioid type with squamous differentiation, is

identified forming an almost circumferential polypoid mass (3.8 x

3.6 x 1.2 cm) involving the endometrial cavity. The tumor invades

0.8 cm into the myometrium (total myometrial thickness, 2.1 cm).

The tumor does not involve the endocervix. Lymphovascular space

invasion is identified. The margins are negative for tumor. There

is a single intramural leiomyoma (0.8 cm in greatest dimension) in

the myometrium. The bilateral ovaries and fallopian tubes are not

involved.

[page 2 of 4]
With available surgical material, [AJCC pT1bN0MX].

PRELIMINARY FROZEN SECTION CONSULTATION:

A. Lymph nodes, para-aortic above the inferior mesenteric artery,

lymphadenectomy: Multiple lymph nodes above the inferior mesenteric artery are negative.

B. Lymph nodes, para-aortic below the inferior mesenteric artery,

lymphadenectomy: Multiple lymph nodes below the inferior mesenteric artery are negative.

C. Lymph nodes, right pelvic, lymphadenectomy: Multiple lymph

nodes are negative.

D. Lymph nodes, left pelvic, lymphadenectomy: Multiple lymph nodes

are negative.

E. Uterus, bilateral ovaries, and fallopian tubes; hysterectomy and

bilateral salpingo-oophorectomy: High grade malignant neoplasm:

grade 3 endometrioid adenocarcinoma with squamous features vs

malignant mixed Mullerian tumor. HOLD to classify and share with

group.

GROSS DESCRIPTION:

A. Received fresh labeled "para-aortic nodes above IMA, laparoscopic" is a 4.0 x 3.0 x 1.0 cm aggregate of adipose and

lymphatic tissue. All lymphatic tissue submitted.

B. Received fresh labeled "para-aortic nodes below IMA, laparoscopic" is a 2.8 x 2.5 x 1.5 cm aggregate of adipose and

[page 3 of 4]
lymphatic tissue. All lymphatic tissue submitted.

C. Received fresh labeled "robotic right pelvic nodes" is a 10.0 x

5.0 x 1.8 cm aggregate of adipose and lymphatic tissue.

All

lymphatic tissue submitted.

D. Received fresh labeled "robotic left pelvic nodes" is a 7.0 x

4.0 x 1.5 cm aggregate of adipose and lymphatic tissue.

All

lymphatic tissue submitted.

E. Received fresh labeled "uterus, left and right tubes and

ovaries" is a 145.0 gram uterus with attached bilateral tubes and

ovaries and an unremarkable cervix. The uterine serosa is smooth.

There is a 3.8 x 3.6 x 1.2 cm polypoid mass in the posterior wall,

left lateral wall and anterior wall of the endometrial cavity which

grossly appears to invade 0.8 cm into the 2.1 cm thick myometrium.

There is a single intramural leiomyoma (0.8 cm in greatest dimension) in the myometrium. There is a 3.3 x 1.7 x 0.9 cm right

ovary with a smooth outer surface and a solid cut surface with a

detached 11.2 x 0.5 cm right fallopian tube. There is a yellow

nodule (0.3 x 0.2 x 0.2 cm) on the surface of the right ovary and a

brown nodule (0.4 x 0.3 x 0.2 cm) in the right ovary.

There is a

2.4 x 1.4 x 1.0 cm left ovary with a ragged outer surface with

adhesions and a solid cut surface with a 10.3 x 0.7 cm left

fallopian tube with adhesions. Representative sections submitted.

BLOCK SUMMARY:

Part A: Para-aortic Lymph Nodes above IMA

1 Above IMA LN 1(A1)

[page 4 of 4]
- 2 Above IMA LN 3(A2)
- 3 Above IMA LN 3(A3)
- 4 Above IMA LN 2(A4)

Part B: Para-aortic Lymph Nodes below IMA

- 1 Below IMA LN 4(B1)
- 2 Below IMA LN 3(B2)
- 3 Below IMA LN 3(B3)

Part C: Robotic Right Pelvic Lymph Nodes

- 1 Rt pelvic LN 4 (C1)
- 2 Rt pelvic LN 3 (C2)
- 3 Rt pelvic LN 1 (C3)
- 4 Rt pelvic LN 1of2 (C4)
- 5 Rt pelvic LN 2of2 (C4)
- 6 Rt pelvic LN 3 (C5)
- 7 Right pelvic LN 3(C6)

Part D: Left Pelvic Lymph Nodes

- 1 Left pelvic LN 5(D1)
- 2 Left pelvic LN 3(D2)
- 3 Left pelvic LN 1of2(D3)
- 4 Left pelvic LN 2of2(D3)
- 5 Left pelvic LN 1(D4)
- 6 Left pelvic LN 3(D5)

Part E: Uterus, tubes, ovaries

- 1 Endometrium post wall-1
- 2 Endometrium post wall-2
- 3 Endometrium post wall-3
- 4 Endometrium post wall-4
- 5 Endometrium post wall-5
- 6 Lower uterine segment
- 7 Cervix
- 8 Right fallopian tube
- 9 Right ovary
- 10 Surface of RT ovary
- 11 Left fallopian tube
- 12 Left ovary
- 13 Surface of LT ovary
- 14 Endometrium post wall-6
- 15 Endometrium post wall-7
- 16 Endometrium post wall-8

Print Malignancy History		☒

Source: NCI Genomic Data Commons file 34096758-e801-4f7f-8fb6-b91d9ac96d97 (TCGA-D1-A0ZS.313BCAEC-965D-4FF4-BAAA-3CAF48C739C6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).